CCDI case PBBMFY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/fa8ec1e2-2c95-498b-98d4-f7a7d31204f9

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Ependymoma, anaplastic: ICD-O-3 morphology code: 9392/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.7 years (6,082 days).

Biospecimens (3 samples)
- Sample 0DC6NT: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DC6NV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DC6O2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
